FM case AD17627 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/492cac3c-6107-464a-836d-5cfb6f9208f9

Female, 39.1 years: Endometrioid adenocarcinoma, NOS (ICD-O-3 8380/3) of the ovary; metastasis biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
